Somatic mutation profile of tumor specimen TCGA-CV-7425-01A (aliquot TCGA-CV-7425-01A-11D-2078-08) from TCGA case TCGA-CV-7425, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 77.7 years (28,368 days).
Specimen TCGA-CV-7425-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ceb3c6c-42ae-4a70-a8ce-f231a3a09ffd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7425-10A (Blood Derived Normal), aliquot TCGA-CV-7425-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9a1a450-d1ba-497a-8475-ae4431ce7788

The open-access MAF lists 118 somatic variants for this specimen: 86 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 30, Nonsense Mutation 10, Splice Region 2, Intron 2, Frame Shift Ins 1, Splice Site 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD2 | c.5035C>T p.R1679* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as rs797044912, CM162086, COSV101245952; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYCN | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057517770, COSV55258811; ClinVar: likely pathogenic; called by muse, varscan2
- ABCC8 | c.2968C>T p.H990Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.216); catalogued as COSV100217705; called by muse, mutect2, varscan2
- ADGRB2 | c.4459G>A p.E1487K (on ENST00000373658 / NM_001364857.2; = p.E1486K on NM_001294335.2) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs1221848989, COSV57078406; called by muse, mutect2, varscan2
- ALDOC | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.763); catalogued as COSV99257254; called by muse, mutect2, varscan2
- ARHGAP35 | c.3850C>T p.R1284W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101351140, COSV101351654; called by muse, mutect2, varscan2
- ATAD5 | c.4657G>C p.E1553Q | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.441); catalogued as COSV100430208; called by muse, mutect2, varscan2
- ATP4A | c.1587C>A p.C529* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99383056; called by muse, mutect2
- ATP7A | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 82/219 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100431646; called by muse, mutect2, varscan2
- ATP9A | c.2674C>G p.L892V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1244902726, COSV100125594; called by muse, mutect2, varscan2
- CACNA1S | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.685); catalogued as rs1352459952, COSV100755355; called by muse, mutect2
- CASP4 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as rs776381340, COSV101274203, COSV67744159; called by muse, mutect2, varscan2
- CASP8 | c.1294C>T p.R432* (on ENST00000432109 / NM_033355.3; = p.R449* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as rs931648756, COSV51845077; called by muse, mutect2, varscan2
- CCDC51 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 15/79 reads (19%) | catalogued as COSV99603392; called by muse, mutect2, varscan2
- CCDC88A | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV55056392; called by muse, mutect2
- CD1E | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs770734231, COSV63771192, COSV63771369; called by muse, mutect2, varscan2
- CDH13 | c.1742A>G p.N581S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs756724897, COSV99230657; called by muse, mutect2, varscan2
- CEACAM18 | c.33G>T p.W11C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV101140307, COSV67283706; called by muse, mutect2, varscan2
- CELF1 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100137217; called by muse, mutect2, varscan2
- CES1 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1306120859, COSV100828801; called by muse, mutect2, varscan2
- COL7A1 | c.5124+1G>T p.X1708_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as rs1322792165, COSV100097626, COSV60396836; called by muse, mutect2, varscan2
- CPNE7 | c.1668G>T p.Q556H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV52012463, COSV99255130; called by muse, mutect2
- CYP8B1 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs145159025, COSV100296287; called by muse, mutect2, varscan2
- DAB2IP | c.981del p.M327Ifs*63 (on ENST00000408936; = p.M299Ifs*63 on NM_032552.3) | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | catalogued as rs1398337063; called by mutect2, pindel, varscan2
- DGKK | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.06); catalogued as rs375123197, COSV101053205, COSV65707564; called by muse, mutect2
- DNAH3 | c.5789C>A p.A1930E | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99770427; called by muse, mutect2
- DOCK4 | c.5734C>T p.R1912C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs769652964, COSV70239329; called by muse, mutect2, varscan2
- DOK1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51211765; called by muse, mutect2, varscan2
- DOK6 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs760566494, COSV66927897, COSV66935189; called by muse, mutect2, varscan2
- DPP10 | c.1354C>A p.L452M | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59663777; called by muse, mutect2, varscan2
- DUOX2 | c.4066G>A p.A1356T | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV101199886; called by muse, mutect2, varscan2
- ERBB2 | c.3016C>T p.R1006C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs780434636, COSV54064867; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM47B | c.1295C>A p.A432E | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.933); catalogued as rs1364485767, COSV100264610, COSV61455690; called by muse, mutect2, varscan2
- FAT4 | c.4228G>A p.V1410M | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781736766, COSV101272852, COSV67881199, COSV67899529; called by muse, mutect2, varscan2
- FIGN | c.1034A>T p.Q345L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs1410900930, COSV100292954; called by muse, mutect2, varscan2
- FREM1 | c.6317G>C p.G2106A | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as rs1196755546, COSV101085415; called by muse, mutect2
- GPRIN1 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV99992157; called by muse, mutect2, varscan2
- HLA-C | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100880959; called by muse, mutect2, varscan2
- HMCN1 | c.16811G>T p.R5604L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs372803002, COSV54898899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HUWE1 | c.4799C>G p.S1600* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99474102; called by muse, mutect2
- HUWE1 | c.3601G>A p.A1201T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99474106; called by muse, mutect2
- IPP | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100739432, COSV63432144, COSV63432196; called by muse, mutect2, varscan2
- ITGB2 | c.897C>T p.F299= | Splice Region (SNP) | VAF 8/40 reads (20%) | catalogued as rs150327269, COSV56608518; called by muse, mutect2, varscan2
- KIF4B | c.2152C>T p.L718F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1347346626, COSV101469401; called by muse, mutect2, varscan2
- KIF5A | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99673557; called by muse, mutect2
- LAMC2 | c.951C>T p.F317= | Splice Region (SNP) | VAF 17/54 reads (31%) | catalogued as rs1309226525, COSV99917932; called by muse, mutect2, varscan2
- LAMP5 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs761575388, COSV55715297; called by muse, mutect2, varscan2
- LIN28B | c.299C>G p.T100R | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100559074; called by muse, mutect2, varscan2
- LRP1B | c.13573G>A p.G4525R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.996); catalogued as rs1031453876, COSV101260535, COSV67199543; called by muse, mutect2, varscan2
- LRP1B | c.6880A>G p.T2294A | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV101260536; called by muse, mutect2, varscan2
- MAN1B1 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 53/108 reads (49%) | catalogued as rs1212283731, COSV100858156; called by muse, mutect2, varscan2
- MLH1 | c.786C>G p.I262M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748553134, COSV51622077; ClinVar: uncertain significance; called by muse, mutect2
- MTERF4 | c.1041T>G p.D347E | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs10203977; called by muse, mutect2, varscan2
- NAPRT | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs753154821, COSV99435550; called by muse, mutect2, varscan2
- NETO1 | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100199686; called by muse, mutect2, varscan2
- NLRP7 | c.2105G>A p.S702N (on ENST00000340844 / NM_206828.3; = p.S674N on NM_139176.3) | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs139797510, COSV60170831; called by muse, mutect2, varscan2
- NR2C2AP | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs773638257, COSV100284622; called by muse, mutect2, varscan2
- NXF3 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs1254179339, COSV101222076; called by muse, mutect2, varscan2
- OSBPL8 | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1361824643, COSV99675560; called by muse, mutect2, varscan2
- PANX3 | c.678C>A p.Y226* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as rs1430636624, COSV52514098, COSV99421394; called by muse, mutect2
- PCDH17 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV100932017; called by muse, mutect2, varscan2
- PCDHA13 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV56483377; called by muse, mutect2, varscan2
- PCDHB8 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 16/153 reads (10%) | catalogued as COSV50761908; called by muse, mutect2
- PCSK5 | c.2855C>A p.S952Y | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV101377697; called by muse, mutect2, varscan2
- RPF1 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139410871; called by muse, mutect2, varscan2
- SLC39A9 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1242147741, COSV99220695; called by muse, mutect2
- SLC3A2 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as rs537183284, COSV100101518; called by muse, mutect2, varscan2
- SLC4A8 | c.1066A>T p.I356F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100177497; called by muse, mutect2, varscan2
- SLITRK2 | c.613A>T p.I205F | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100158190; called by muse, mutect2, varscan2
- SNRNP200 | c.6088C>T p.R2030C | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs150442718; called by muse, mutect2, varscan2
- SNTG2 | c.165G>C p.Q55H | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs540106357, COSV100424664; called by muse, mutect2, varscan2
- SPTA1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs767319344, COSV100935504, COSV63757453; called by muse, mutect2, varscan2
- SRPX | c.1342A>G p.R448G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs1190100852, COSV100656251; called by muse, mutect2, varscan2
- SYNE1 | c.11231G>A p.G3744E (on ENST00000367255 / NM_182961.4; = p.G3729E on NM_033071.3) | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs999063074, COSV99577604; called by muse, mutect2, varscan2
- TADA3 | c.1272G>C p.E424D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1245567569, COSV100113113; called by muse, mutect2, varscan2
- TBX19 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.062); catalogued as rs752325337, COSV100892410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM3 | c.4582G>T p.G1528C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs980396297, COSV101305456; called by muse, mutect2, varscan2
- THBS4 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1170686622, COSV100644426; called by muse, mutect2, varscan2
- TMEM176B | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs144557912; called by muse, mutect2, varscan2
- TMEM198 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as rs763015024, COSV54717319; called by muse, mutect2, varscan2
- TOP3B | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as rs967946882, COSV100592349, COSV100592782; called by muse, mutect2, varscan2
- TRHDE | c.2138C>A p.S713Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99672387; called by muse, mutect2, varscan2
- TRPM3 | c.4273G>T p.V1425L (on ENST00000357533 / NM_001366142.2; = p.V1280L on NM_020952.6) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as COSV100678655; called by muse, mutect2, varscan2
- ZNF616 | c.759T>A p.N253K | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771231573, COSV57511035; called by muse, mutect2, varscan2
- EPHA2 | c.1182dup p.T395Hfs*59 | Frame Shift Ins (INS) | VAF 6/17 reads (35%) | called by mutect2, pindel, varscan2
- FBXW7 | c.1423_1425del p.V475del (on ENST00000281708 / NM_001349798.2; = p.V395del on NM_018315.5) | In Frame Del (DEL) | VAF 14/66 reads (21%) | called by pindel, varscan2
- BCORL1 | c.2424G>A p.T808= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs138691600, COSV54396533; called by muse, mutect2, varscan2
- CHRNA9 | c.333C>T p.L111= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs148584579; called by muse, mutect2, varscan2
- DGKB | c.405G>A p.L135= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV51810359; called by muse, mutect2, varscan2
- DNAH7 | c.7692C>G p.L2564= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs750777101, COSV100417429, COSV56784053; called by muse, mutect2, varscan2
- HIBCH | c.561C>T p.L187= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100676283; called by muse, mutect2, varscan2
- INTS8 | c.1659C>G p.V553= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV100569433, COSV58248766; called by muse, mutect2, varscan2
- IQCH | c.364C>T p.L122= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV100246316; called by muse, mutect2, varscan2
- L3MBTL4 | c.63C>T p.D21= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as rs759827055, COSV53115083; called by muse, mutect2, varscan2
- MCM8 | c.1113G>A p.K371= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs1466275044, COSV99496220; called by muse, mutect2, varscan2
- MSLN | c.792G>A p.P264= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs905799484, COSV99558710; called by muse, mutect2, varscan2
- MYH4 | c.1290G>A p.L430= | Silent (SNP) | VAF 17/212 reads (8%) | catalogued as rs1316423281, COSV99702172; called by muse, mutect2
- NCOA2 | c.1038T>C p.L346= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV101476054; called by muse, mutect2, varscan2
- NEGR1 | c.295A>C p.R99= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs1183366643, COSV100165925; called by muse, mutect2, varscan2
- NPHS2 | c.246G>A p.A82= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100858171; called by muse, mutect2, varscan2
- NTF4 | c.543C>T p.T181= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs974105707, COSV100032231, COSV100032314; called by muse, mutect2, varscan2
- PCDHA3 | c.1092A>T p.P364= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV100793720; called by muse, varscan2
- PLCXD3 | c.156T>C p.P52= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100126308; called by muse, mutect2, varscan2
- POU3F2 | c.867G>A p.A289= | Silent (SNP) | VAF 44/216 reads (20%) | catalogued as rs751058060, COSV60408909; called by muse, mutect2, varscan2
- PRAME | c.1203C>T p.S401= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV101287235; called by muse, mutect2, varscan2
- SART1 | c.417C>T p.A139= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs1385900488, COSV100409134; called by muse, mutect2
- SLC4A11 | c.1425C>T p.A475= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV101196128; called by muse, mutect2, varscan2
- SYNJ2 | c.372C>G p.L124= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100840641; called by muse, mutect2, varscan2
- TEX55 | c.930G>C p.V310= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99817808; called by muse, mutect2, varscan2
- TRAF3IP1 | c.445T>C p.L149= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100967070; called by muse, mutect2
- UBR5 | c.2767T>C p.L923= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as rs1226638674, COSV99642272; called by muse, mutect2, varscan2
- UNC45B | c.2340G>A p.A780= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs754204161, COSV52096708; called by muse, mutect2
- WDR88 | c.237G>A p.P79= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV50112126; called by muse, mutect2, varscan2
- ZNF536 | c.1014C>A p.G338= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100835344, COSV100835821; called by muse, mutect2
- ZNF613 | c.105C>T p.D35= | Silent (SNP) | VAF 31/140 reads (22%) | catalogued as rs766471007, COSV53272960; called by muse, mutect2, varscan2
- ZNF804B | c.756C>G p.P252= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100306042, COSV60857174; called by muse, mutect2, varscan2
- EBAG9 | c.522-986C>T | Intron (SNP) | VAF 50/197 reads (25%) | catalogued as COSV100520900; called by muse, mutect2, varscan2
- UROC1 | c.903-580C>A | Intron (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99332333; called by muse, mutect2, varscan2
